Somatic mutation profile of tumor specimen ALCH-B2R3-TTP1-A (aliquot ALCH-B2R3-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2R3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.8 years (18,910 days).
Specimen ALCH-B2R3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a91691a-31b2-457e-a92c-50de471d94aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2R3-NB1-A (Blood Derived Normal), aliquot ALCH-B2R3-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d40da519-cb5d-46fc-8044-9bf7d0ae9f8d

The open-access MAF lists 149 somatic variants for this specimen: 93 protein-altering or splice-affecting, 42 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 42, Nonsense Mutation 8, Intron 8, 5'Flank 3, 5'UTR 2, Splice Site 1, Splice Region 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC73 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 103/787 reads (13%) | catalogued as rs886041278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 96/250 reads (38%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 484/932 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.10367A>C p.E3456A | Missense Mutation (SNP) | VAF 256/1576 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as rs1375645030; called by muse, mutect2, varscan2
- C17orf78 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 57/496 reads (11%) | catalogued as rs755385153; called by muse, mutect2, varscan2
- CALR3 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 142/757 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54170143; called by muse, mutect2, varscan2
- CARD14 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 101/479 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371741250; called by muse, mutect2, varscan2
- CNST | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 113/914 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1432372462; called by muse, mutect2, varscan2
- DGCR2 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV54223208; called by muse, mutect2, varscan2
- DNAH8 | c.6421C>G p.L2141V | Missense Mutation (SNP) | VAF 62/541 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766688342, COSV59460261; called by muse, mutect2, varscan2
- DYNC1H1 | c.11729G>C p.R3910T | Missense Mutation (SNP) | VAF 237/1469 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs762581002; called by muse, mutect2, varscan2
- FOXA2 | c.730G>A p.E244K (on ENST00000377115 / NM_153675.3; = p.E250K on NM_021784.5) | Missense Mutation (SNP) | VAF 77/745 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV65795534, COSV65796814; called by muse, mutect2, varscan2
- FSCB | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1162808412, COSV61219458; called by mutect2, varscan2
- GLUL | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 375/1296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59381638; called by muse, mutect2, varscan2
- INAVA | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 174/593 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs980828253, COSV66255768; called by muse, mutect2, varscan2
- KIT | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 155/589 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.172); catalogued as COSV99853496; called by muse, mutect2, varscan2
- KRT8 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 168/962 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53176576; called by muse, varscan2
- LPIN2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs776274863, COSV55242303; called by muse, mutect2, varscan2
- LRFN3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV55818900; called by muse, mutect2, varscan2
- MCM3AP | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV52440434; called by muse, mutect2, varscan2
- MOAP1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52092633; called by muse, mutect2, varscan2
- MOAP1 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.093); catalogued as COSV99365781; called by muse, mutect2, varscan2
- NFKBIE | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 129/427 reads (30%) | PolyPhen benign (0.027); catalogued as COSV99069956; called by muse, mutect2, varscan2
- NUP188 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.76); catalogued as rs1477781433; called by muse, mutect2, varscan2
- OAS3 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs752197304, COSV57444116; called by muse, mutect2, varscan2
- OS9 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 170/908 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs1291096769; called by muse, mutect2, varscan2
- PEX10 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1343463457; called by muse, mutect2, varscan2
- RCOR2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 149/712 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs1014102129, COSV56849907, COSV56850689; called by muse, mutect2, varscan2
- SFRP1 | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 201/956 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV55176968; called by muse, mutect2, varscan2
- SHISA4 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100748226; called by muse, mutect2
- SHLD2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100079412; called by muse, mutect2, varscan2
- SLC2A7 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 42/327 reads (13%) | catalogued as COSV68901243; called by muse, varscan2
- SLU7 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV51787617; called by muse, mutect2, varscan2
- SNX27 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 74/582 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV64327545; called by muse, mutect2, varscan2
- TMTC2 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs753154903; called by muse, mutect2
- ZNF878 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 62/139 reads (45%) | catalogued as rs189074815, COSV101521242, COSV72156010; called by muse, mutect2, varscan2
- ABCA10 | c.4516C>G p.Q1506E | Missense Mutation (SNP) | VAF 81/449 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ABCA9 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS12 | c.1625C>G p.P542R | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AKR1B15 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 69/660 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ANKRD10 | c.849T>A p.H283Q | Missense Mutation (SNP) | VAF 79/1082 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARHGAP23 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ATAT1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CENPF | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 76/495 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CENPF | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CENPF | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 79/457 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CEP76 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD8 | c.7445C>T p.S2482L (on ENST00000646647 / NM_001170629.2; = p.S2203L on NM_020920.4) | Missense Mutation (SNP) | VAF 150/1060 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CHRNA6 | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 256/431 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN15 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 98/397 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CNTRL | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, varscan2
- COL20A1 | c.2368C>G p.P790A | Missense Mutation (SNP) | VAF 112/728 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); called by muse, varscan2
- DMTF1 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 109/523 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMWD | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 92/473 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.4018G>C p.E1340Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EPB41L4B | c.1945A>G p.R649G | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EPS15 | c.1919-1G>T p.X640_splice | Splice Site (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- FYB1 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- HERC1 | c.746A>T p.E249V | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HLCS | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 295/1410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IP6K3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 369/1326 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KLK3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAJIN | c.384C>T p.V128= | Splice Region (SNP) | VAF 153/362 reads (42%) | called by muse, mutect2, varscan2
- MOAP1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MRPS34 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO7B | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- MYOF | c.2698C>G p.L900V | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NHSL2 | c.1496G>C p.R499T (on ENST00000510661; = p.R865T on NM_001013627.2) | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NRIP1 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSDHL | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 118/926 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NTNG2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 162/630 reads (26%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- OR5P3 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PAPOLB | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PDIA5 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RBM15 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 231/398 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- RNF213 | c.9501C>A p.N3167K | Missense Mutation (SNP) | VAF 101/722 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN4A | c.4816G>C p.E1606Q | Missense Mutation (SNP) | VAF 247/1285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC1A7 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SLC5A5 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 168/864 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SMARCE1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, varscan2
- STYXL2 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNPO2 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- USF1 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 105/654 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- UTP25 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VMP1 | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 61/183 reads (33%) | called by muse, mutect2, varscan2
- VPS37D | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 177/786 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WDFY3 | c.5678A>G p.D1893G | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- WFS1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 236/849 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZBTB34 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 132/525 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZMAT2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.05); called by muse, varscan2
- ZNF266 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ZNF829 | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- ZNF829 | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- ABCG1 | c.1020G>A p.L340= | Silent (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- ATP13A4 | c.2931C>T p.F977= | Silent (SNP) | VAF 163/423 reads (39%) | catalogued as COSV61323885; called by muse, mutect2, varscan2
- CACNA1E | c.4662C>T p.I1554= | Silent (SNP) | VAF 60/385 reads (16%) | catalogued as COSV100701910; called by muse, mutect2, varscan2
- CCN6 | c.516G>A p.K172= | Silent (SNP) | VAF 117/974 reads (12%) | catalogued as COSV100036884, COSV57890769; called by muse, mutect2, varscan2
- COL20A1 | c.2367G>T p.V789= | Silent (SNP) | VAF 116/728 reads (16%) | catalogued as rs1482731516; called by muse, mutect2, varscan2
- CPA4 | c.864G>C p.V288= | Silent (SNP) | VAF 106/572 reads (19%) | called by muse, mutect2, varscan2
- CSAD | c.633C>G p.V211= (on ENST00000444623 / NM_001244705.2; = p.V238= on NM_015989.5) | Silent (SNP) | VAF 126/580 reads (22%) | called by muse, mutect2, varscan2
- CTAGE15 | c.930T>C p.P310= | Silent (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- DEFB115 | c.246G>A p.E82= | Silent (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
- DENND4A | c.4812C>A p.L1604= | Silent (SNP) | VAF 75/350 reads (21%) | called by muse, mutect2, varscan2
- DNM2 | c.1275G>C p.L425= | Silent (SNP) | VAF 411/1116 reads (37%) | catalogued as rs1162156222, COSV100117783; called by muse, mutect2, varscan2
- ELOVL6 | c.555G>A p.A185= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as rs145349219, COSV56429729; called by muse, mutect2, varscan2
- FANCL | c.456C>G p.L152= | Silent (SNP) | VAF 70/272 reads (26%) | called by muse, mutect2, varscan2
- FBXO28 | c.792C>G p.L264= | Silent (SNP) | VAF 68/499 reads (14%) | called by muse, mutect2, varscan2
- HNRNPAB | c.36G>A p.T12= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- IDO2 | c.24G>T p.V8= (on ENST00000389060; = p.V21= on NM_194294.2) | Silent (SNP) | VAF 50/874 reads (6%) | called by muse, mutect2
- LRFN3 | c.504C>G p.L168= | Silent (SNP) | VAF 72/345 reads (21%) | catalogued as rs760768387, COSV55817996; called by muse, mutect2, varscan2
- MAPK8IP2 | c.834G>C p.L278= | Silent (SNP) | VAF 130/475 reads (27%) | called by muse, mutect2, varscan2
- MIB1 | c.2454G>A p.E818= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as rs373113913; called by muse, mutect2, varscan2
- NOX3 | c.630C>T p.F210= | Silent (SNP) | VAF 41/226 reads (18%) | called by muse, mutect2, varscan2
- PARP14 | c.1392G>A p.E464= | Silent (SNP) | VAF 65/338 reads (19%) | called by muse, mutect2, varscan2
- PKNOX2 | c.1029G>A p.R343= | Silent (SNP) | VAF 120/242 reads (50%) | called by muse, mutect2, varscan2
- PNPLA5 | c.636C>T p.F212= | Silent (SNP) | VAF 84/375 reads (22%) | catalogued as rs765540539; called by muse, mutect2, varscan2
- RNFT2 | c.1152C>T p.C384= | Silent (SNP) | VAF 121/664 reads (18%) | catalogued as rs750175095, COSV57488501; called by muse, varscan2
- RPN1 | c.1536C>T p.L512= | Silent (SNP) | VAF 667/1029 reads (65%) | called by muse, mutect2, varscan2
- SCAF11 | c.2064G>A p.L688= | Silent (SNP) | VAF 37/265 reads (14%) | catalogued as rs952824873; called by muse, mutect2, varscan2
- SLC17A4 | c.735C>G p.L245= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as COSV100930666, COSV64955654; called by muse, mutect2, varscan2
- SLC47A1 | c.1197G>C p.L399= | Silent (SNP) | VAF 170/368 reads (46%) | catalogued as COSV54498840; called by muse, mutect2, varscan2
- SLC9A9 | c.1261C>T p.L421= | Silent (SNP) | VAF 90/404 reads (22%) | catalogued as COSV57246241; called by muse, mutect2, varscan2
- TDP1 | c.1671G>A p.Q557= | Silent (SNP) | VAF 104/700 reads (15%) | called by mutect2, varscan2
- TGIF1 | c.327C>T p.I109= (on ENST00000330513 / NM_001374396.1; = p.I129= on NM_003244.4) | Silent (SNP) | VAF 167/791 reads (21%) | catalogued as rs1478445900; called by muse, mutect2, varscan2
- TLE1 | c.2004C>T p.T668= | Silent (SNP) | VAF 127/410 reads (31%) | catalogued as rs2229270; called by muse, mutect2, varscan2
- TRIM36 | c.918C>A p.L306= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- ULK2 | c.2502G>C p.L834= | Silent (SNP) | VAF 57/293 reads (19%) | called by muse, mutect2, varscan2
- WDR19 | c.2085C>A p.I695= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, varscan2
- WDR91 | c.426C>T p.T142= | Silent (SNP) | VAF 66/291 reads (23%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.7065C>A p.I2355= | Silent (SNP) | VAF 165/1040 reads (16%) | called by muse, mutect2, varscan2
- ZNF133 | c.1272C>T p.T424= (on ENST00000316358 / NM_001352454.2; = p.T423= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV100315557; called by mutect2, varscan2
- ZNF160 | c.2094T>G p.T698= | Silent (SNP) | VAF 37/130 reads (28%) | called by muse, mutect2, varscan2
- ZNF536 | c.1146C>T p.F382= | Silent (SNP) | VAF 72/385 reads (19%) | called by muse, mutect2, varscan2
- ZNF541 | c.1953G>A p.L651= | Silent (SNP) | VAF 167/363 reads (46%) | called by muse, mutect2, varscan2
- ZRANB3 | c.2859G>C p.L953= | Silent (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38484C>G | Intron (SNP) | VAF 149/579 reads (26%) | called by muse, mutect2, varscan2
- CCDC144CP | n.2113G>T | RNA (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- CERS5 | c.197+1201G>C | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- GATM | chr15:45378585 C>G | 5'Flank (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- IK | c.177-14C>G | Intron (SNP) | VAF 50/205 reads (24%) | called by muse, mutect2, varscan2
- NDUFB1 | c.-124+34G>A | Intron (SNP) | VAF 80/452 reads (18%) | catalogued as rs754369897, COSV54097998, COSV54099250; called by muse, mutect2, varscan2
- NUP160 | c.2676+56G>C | Intron (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- POR | c.-4-10126C>T | Intron (SNP) | VAF 74/187 reads (40%) | called by muse, mutect2, varscan2
- PSMC3IP | chr17:42577771 G>C | 5'Flank (SNP) | VAF 162/673 reads (24%) | called by muse, mutect2, varscan2
- RGPD4 | c.-28G>A | 5'UTR (SNP) | VAF 184/719 reads (26%) | catalogued as rs556540233, COSV100736318; called by muse, mutect2, varscan2
- SNORA72 | chr1:224175900 C>A | 5'Flank (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- TJP1 | c.-24C>T | 5'UTR (SNP) | VAF 19/69 reads (28%) | catalogued as rs1175394784; called by muse, mutect2, varscan2
- UNC93B1 | c.97-34G>C | Intron (SNP) | VAF 70/146 reads (48%) | called by muse, varscan2
- ZMYND8 | c.26-8503C>G | Intron (SNP) | VAF 97/547 reads (18%) | called by muse, mutect2, varscan2
